Surgical pathology report (de-identified scan), TCGA case TCGA-55-A48Y, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-A48Y-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY:

PROCEDURE DATE: RECEIVED DATE: REPORT DATE:

COPY TO: [REDACTED]

KD-03

Adenocarcinoma, NOS

814013

Site: lung, lower lobe

9-11-12
RD

C34.3

Pre-Op Diagnosis
Left lung mass
Post-Op Diagnosis
Same as above
Clinical History
Nothing indicated
Gross Description:
Five parts

Container labeled "[REDACTED] 1 - level 9 lymph node left lung"
has a 1.8 x 1.0 x 0.5 cm fleshy gray-tan to pink nodule surrounded
by a small amount of yellow adipose tissue. The specimen is bisected
and entirely submitted in a single cassette.

Container labeled "[REDACTED] 2 - level 10 lymph node left
lung" has two nodular portions of rubbery gray-tan fleshy tissue
measuring 1.5 x 1.0 x 0.5 cm and 2.0 x 1.0 x 0.5 cm. These are
received along with 1.3 x 1.0 x 0.5 cm of similar fleshy tissue
fragments with associated yellow adipose tissue. The smaller nodule
is bisected and submitted labeled A. The larger nodule is bisected
and submitted labeled B. Remaining tissue fragments are submitted
labeled C.

Container labeled "[REDACTED] 3 - left lower lobe" has a 231
gram previously partially inked, partially sectioned portion of
recognizable pulmonary parenchyma grossly consistent with left lower
lobe of lung. The specimen as received on reconstruction is 15.6 x
9.6 x 5.9 cm and has as the margin of resection the stapled
bifurcation of the tertiary bronchi, as well as several additional
vascular and parenchymal staple lines. Adjacent to the bronchus is a
1.5 x 1.0 x 0.7 cm lobulated fleshy gray-black nodule. The pleura is
slightly wrinkled gray-tan to pink. On the upper anterolateral

[page 2 of 3]
aspect at a point approximately 4.0 cm from the upper portion of the specimen there is an area of indurated umbilication over an area of 6.5 cm extending onto the lateral aspect. The anterior extending to the lateral aspect of this indurated pleura is overlaid by gray-tan fibrinous material. The specimen has been previously partially sectioned within this area to reveal a well defined 5.5 x 5.5 x 5.4 cm lobulated intraparenchymal gritty gray-tan fibrotic lesion. This extends grossly focally to within 0.2 cm of the pleura. On sectioning, this has a necrotic gray-tan focally anthracotic-streaked fibrotic cut surface and grossly appears at its nearest point 1.6 cm from the bronchial margin. A bronchial connection is grossly identified. On the medial aspect of the specimen the pleura is taut over the lesion. In the area of the pleural staple line margins the lesion grossly appears to focally extend to within 0.2 cm of these staple lines. The lesion grossly abuts and focally compresses several large vascular structures but does not grossly appear to extend into them. The specimen is received after tissue harvest for genomic study. Within the specimen container are two tissue cassettes labeled 'The remaining parenchyma is spongy, partially collapsed, gray-pink to red with moderate anthracotic streaking and areas of apparent gross emphysematous change. Representative sections are submitted labeled as follows: A - shaved bronchial margin; B - peribronchial nodule, sectioned; C - lesion with bronchial connection; D - lesion to fibrinous material on pleura; E-H - lesion and surrounding tissue; I - random uninvolved parenchyma.

Container labeled "[REDACTED] 4 - level 6 lymph node left lung" has a 1.0 x 0.8 x 0.5 cm nodular portion of partially fragmented gray-brown fleshy tissue with a small amount of associated yellow adipose tissue. This is received along with a 1.2 x 1.0 x 0.3 cm portion of yellow adipose tissue with a few adherent fragments of gray-black fleshy tissue up to 0.3 cm. The nodule is bisected and the specimen entirely submitted in a single cassette.

Container labeled "[REDACTED] 5 - level 5 lymph node left lung" has a 1.6 x 1.2 x 0.4 cm nodular portion of gray-pink fleshy tissue which is bisected and entirely submitted in a single cassette.

Microscopic Description:

Reviewed are slides labeled "[REDACTED]". An elastic stain is performed (with working control) and supports the following diagnosis.

Final Diagnosis

Lymph node, level 9, left lung, biopsy:

One lymph node negative for metastatic carcinoma (0/1).

Lymph nodes, level 10, left lung, biopsy:

Three lymph nodes negative for metastatic carcinoma (0/3).

Lung, left lower lobe, lobectomy:

Tumor characteristics:

Specimen integrity: Intact.

Specimen laterality: Left lower lobe.

Histologic type: Adenocarcinoma.

Histologic grade: Moderately differentiated (grade II).

Tumor site: Left lower lobe.

Tumor focality: Unifocal.

Tumor size: 5.5 x 5.5 x 5.4 cm.

Visceral pleural invasion: Tumor penetrates through elastic layer

[page 3 of 3]
into pleura but not to
pleural surface.

Lymphovascular space invasion: No unequivocal lymphovascular space
invasion identified.

Tumor extension: Confined to lung.

Treatment effect: Not identified/not known.

Surgical margin status:

Tumor distance from bronchial margin: 1.6 cm.

Tumor distance from parenchymal margin: 0.2 cm.

Tumor distance from pleural surface: 0.2 cm.

~~Lymph node status:~~

Total number of lymph nodes received (with lobectomy specimen
only): One.

Total number of lymph nodes containing metastatic carcinoma: Zero
(0/1); seven lymph
nodes received with all specimen parts (0/7).

Other:

Stage: pT2b N0

Lymph node, level 6, left lung, biopsy:

One lymph node negative for metastatic carcinoma (0/1).

Lymph node, level 5, left lung, biopsy:

One lymph node negative for metastatic carcinoma (0/1). PAS 9
SPC-A

Comments

An elastic stain is performed (with working controls) and supports
the above diagnosis.

At the request of the undersigned pathologist, these slides have
been additionally reviewed by Dr. [REDACTED], who concurs with the
diagnosis.

This report has been finalized at the [REDACTED]

<Sign Out Dr. Signature>

Source: NCI Genomic Data Commons file d46e47d6-159f-4d1a-9026-bf6a118c19da (TCGA-55-A48Y.3542521A-EA16-4CD1-A61A-1FB3AE928FC9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).